Somatic mutation profile of tumor specimen TCGA-23-2643-01A (aliquot TCGA-23-2643-01A-01D-1526-09) from TCGA case TCGA-23-2643, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.2 years (27,093 days).
Specimen TCGA-23-2643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cda33ca0-f901-4dca-be72-288cc14dd5dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2643-10A (Blood Derived Normal), aliquot TCGA-23-2643-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db92fd5a-0bcb-4447-a75a-d41722ce58e1

The open-access MAF lists 50 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 32, Silent 9, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKHD1 | c.9998+1G>T p.X3333_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as rs1554217691, COSV100583858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 222/275 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1558C>T p.L520F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58053868; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6719A>T p.D2240V | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as COSV99783893; called by muse, mutect2
- APEH | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV56526370; called by muse, mutect2, varscan2
- ARAF | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.551); catalogued as rs1387037979, COSV99283348; called by muse, mutect2
- ATR | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV63391705; called by muse, mutect2, varscan2
- CLIC6 | c.1688A>G p.H563R (on ENST00000360731 / NM_001317009.2; = p.H545R on NM_053277.3) | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs150066189; called by muse, mutect2, varscan2
- CST2 | c.369C>G p.Y123* | Nonsense Mutation (SNP) | VAF 91/633 reads (14%) | catalogued as rs13041691, COSV59030346, COSV59030991; called by muse, mutect2, varscan2
- CTCFL | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 74/397 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs749570710, COSV54778528; called by muse, mutect2, varscan2
- GFAP | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs777820983, COSV53653420; called by muse, mutect2, varscan2
- GSTA4 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 284/496 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63955981; called by muse, mutect2, varscan2
- GUSB | c.14C>G p.S5W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV59223724; called by muse, mutect2, varscan2
- HHATL | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.057); catalogued as COSV100124539; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as COSV61256081; called by muse, mutect2, varscan2
- KLF10 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1367703730, COSV53436720; called by muse, mutect2, varscan2
- KLRC1 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV104418017, COSV61725952; called by muse, mutect2, varscan2
- KREMEN2 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53557313; called by muse, varscan2
- MMP17 | c.951C>A p.D317E | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs763158219, COSV62181230; called by muse, mutect2, varscan2
- NUDT17 | c.104C>G p.T35R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57908512; called by muse, mutect2, varscan2
- OXSM | c.1154A>G p.H385R | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55002560; called by muse, mutect2, varscan2
- PANX2 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV50311966; called by muse, mutect2, varscan2
- PARP8 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV55866288; called by muse, mutect2, varscan2
- PBOV1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 50/212 reads (24%) | catalogued as rs373323732, COSV52449710; called by muse, mutect2
- PNMA5 | c.509C>A p.P170Q | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62626224; called by muse, mutect2, varscan2
- PTPRH | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.513); catalogued as COSV99671254; called by muse, mutect2, varscan2
- PTPRH | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99671255; called by muse, mutect2, varscan2
- RADX | c.642C>T p.S214= | Splice Region (SNP) | VAF 21/53 reads (40%) | catalogued as COSV65319953; called by muse, mutect2, varscan2
- SCML2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV99319256; called by muse, mutect2
- SEMA6C | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 108/656 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs769914081, COSV59007263; called by muse, mutect2, varscan2
- SLC12A4 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57935016; called by muse, mutect2, varscan2
- ST6GAL2 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 58/276 reads (21%) | PolyPhen probably damaging (0.996); catalogued as COSV62418017; called by muse, mutect2, varscan2
- TAF1 | c.2523G>A p.W841* (on ENST00000373790 / NM_138923.4; = p.W862* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 78/191 reads (41%) | catalogued as COSV52123811; called by muse, mutect2, varscan2
- TAF1 | c.3259A>C p.M1087L (on ENST00000373790 / NM_138923.4; = p.M1108L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as rs1169468265, COSV52123827, COSV52129495; called by muse, mutect2, varscan2
- TEP1 | c.6235G>A p.G2079R | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs201759110, COSV52999053; called by muse, mutect2, varscan2
- TRAM1L1 | c.905C>G p.S302W | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs562701564, COSV60293190, COSV60293312; called by muse, mutect2, varscan2
- UCP2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV60105254; called by muse, mutect2, varscan2
- ZNF468 | c.1070G>C p.C357S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54696780; called by muse, mutect2, varscan2
- ASNS | c.569del p.L190* | Frame Shift Del (DEL) | VAF 15/176 reads (9%) | called by mutect2, pindel
- FBP1 | c.119_127del p.T40_V42del | In Frame Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- THBS4 | c.936_945del p.C313Afs*27 | Frame Shift Del (DEL) | VAF 51/170 reads (30%) | called by mutect2, pindel, varscan2
- ANK2 | c.1119G>A p.A373= | Silent (SNP) | VAF 100/202 reads (50%) | catalogued as rs139123934, COSV52156920; ClinVar: likely benign; called by muse, mutect2, varscan2
- CENPU | c.1200C>G p.A400= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV55658494, COSV55659176; called by muse, mutect2, varscan2
- COPS7A | c.366G>A p.L122= | Silent (SNP) | VAF 277/628 reads (44%) | catalogued as COSV57527268; called by muse, mutect2, varscan2
- NGEF | c.441C>T p.A147= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as COSV50952045; called by muse, mutect2, varscan2
- RREB1 | c.2508G>C p.A836= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV58564788; called by muse, mutect2, varscan2
- SKOR1 | c.360C>T p.R120= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as rs961360222, COSV58249586; called by muse, mutect2, varscan2
- SMPX | c.238C>T p.L80= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as COSV101069808; called by muse, mutect2
- SUMO3 | c.81C>A p.S27= | Silent (SNP) | VAF 47/444 reads (11%) | catalogued as COSV60538506; called by muse, mutect2, varscan2
- TES | c.186A>G p.K62= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV64043579; called by muse, mutect2, varscan2
